Gene-level copy-number profile of tumor specimen TCGA-BB-8596-01A from TCGA case TCGA-BB-8596, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Hypopharynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 69.6 years (25,408 days).
Specimen TCGA-BB-8596-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.79781e9f-ee8e-4ceb-be68-5b72ec120727.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BB-8596-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/db91157a-097d-460d-b80a-059c74964721

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 48,018; copy number 3: 11,621; copy number 4: 135; copy number 5: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BB-8596-01A-11D-2390-01): tumor purity 0.25, ploidy 2.58, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 45 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:56,848,478–57,515,780, 24 genes, copy number 5: LINC02735, FADS2B, OR5AK3P, OR5AK2, OR5AK1P, OR5BQ1P, OR5AK4P, OR5AO1P, OR5BP1P, LRRC55, APLNR, TNKS1BP1, AP000781.1, SSRP1, P2RX3, PRG3, PRG2, AP000781.2, SLC43A3, RNA5SP341, RN7SKP259, RTN4RL2, AP002893.1, SLC43A1.
- chr11:59,806,140–60,417,756, 21 genes, copy number 5: MRPL16, CBLIF, TCN1, OOSP3, SRD5A3P1, OOSP1, AP000790.1, OOSP4A, OOSP4B, OOSP2, MS4A3, AP000790.2, MS4A2, LINC02705, MS4A6A, MS4A4A, MS4A4E, MIR6503, MS4A6E, MS4A7, MS4A14.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
